Somatic mutation profile of tumor specimen TCGA-AA-A03F-01A (aliquot TCGA-AA-A03F-01A-11W-A096-10) from TCGA case TCGA-AA-A03F, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage III; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-AA-A03F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8a319a3-17de-467a-94f3-4d3dd7917a4c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-A03F-11A (Solid Tissue Normal), aliquot TCGA-AA-A03F-11A-12W-A096-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/949a5161-430f-479d-b224-de033b9e0031

The open-access MAF lists 138 somatic variants for this specimen: 105 protein-altering or splice-affecting, 30 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 96, Silent 30, Nonsense Mutation 6, Frame Shift Ins 1, RNA 1, 5'Flank 1, Frame Shift Del 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2413C>T p.R805* | Nonsense Mutation (SNP) | VAF 27/81 reads (33%) | catalogued as rs587779783, CM960067, COSV57322578; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 73/224 reads (33%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 149/462 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ING1 | c.1015C>T p.R339* | Nonsense Mutation (SNP) | VAF 24/59 reads (41%) | hotspot (GDC flag); catalogued as COSV58167363; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 62/208 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 67/172 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA10 | c.3894G>T p.M1298I | Missense Mutation (SNP) | VAF 79/214 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV52227437; called by muse, mutect2, varscan2
- ACVR1B | c.646G>A p.G216S | Missense Mutation (SNP) | VAF 280/378 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57777072; called by muse, mutect2, varscan2
- ALG6 | c.865A>C p.K289Q | Missense Mutation (SNP) | VAF 136/394 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as COSV54766955; called by muse, mutect2, varscan2
- AMZ1 | c.385G>A p.V129I | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs371188824; called by muse, mutect2, varscan2
- ANAPC2 | c.1487G>A p.R496Q | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.64); catalogued as rs768895745, COSV100118928, COSV60571651; called by muse, mutect2, varscan2
- ARMCX1 | c.434C>A p.P145Q | Missense Mutation (SNP) | VAF 79/195 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.915); catalogued as COSV100863250; called by muse, mutect2, varscan2
- ASCC3 | c.3067C>A p.Q1023K | Missense Mutation (SNP) | VAF 100/327 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV61231868; called by muse, mutect2, varscan2
- ASTN2 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.72); catalogued as rs1178861666, COSV57793827, COSV57798910; called by muse, mutect2, varscan2
- ATAD3A | c.1285G>A p.V429M | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as rs1338018303, COSV59235026; called by muse, mutect2, varscan2
- ATP7A | c.3499G>A p.A1167T | Missense Mutation (SNP) | VAF 93/268 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV58451314; called by muse, mutect2, varscan2
- BRD7 | c.971A>G p.E324G | Missense Mutation (SNP) | VAF 127/402 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as COSV101165073; called by muse, mutect2, varscan2
- CAMTA2 | c.1498C>A p.P500T | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as COSV100772865; called by muse, mutect2, varscan2
- CCL7 | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 100/281 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as rs149253093; called by muse, mutect2, varscan2
- CD93 | c.874C>G p.R292G | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as COSV55665675, COSV55667177, COSV99849651; called by muse, mutect2
- CHD4 | c.2885G>A p.R962H (on ENST00000357008 / NM_001363606.2; = p.R975H on NM_001273.5) | Missense Mutation (SNP) | VAF 87/259 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58896611, COSV58901386; called by muse, mutect2, varscan2
- CIITA | c.2515C>T p.R839C | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as rs1175375174, COSV60860516; called by muse, mutect2, varscan2
- CLIP4 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 115/308 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as rs762227443, COSV60747019; called by muse, mutect2, varscan2
- COL12A1 | c.6941G>C p.R2314P | Missense Mutation (SNP) | VAF 170/596 reads (29%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.898); catalogued as COSV100486658; called by muse, mutect2, varscan2
- COL4A1 | c.1943C>G p.P648R | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.898); catalogued as COSV101011622; called by muse, mutect2
- CWF19L2 | c.2626G>A p.A876T | Missense Mutation (SNP) | VAF 183/594 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.098); catalogued as rs766665594, COSV99980019; called by mutect2, varscan2
- DHX9 | c.2557C>T p.R853* | Nonsense Mutation (SNP) | VAF 16/483 reads (3%) | catalogued as COSV62361251; called by muse, mutect2
- DKK1 | c.539A>C p.H180P | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.731); catalogued as COSV64760615; called by muse, mutect2, varscan2
- DPYD | c.1560A>C p.E520D | Missense Mutation (SNP) | VAF 84/225 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100929512; called by muse, mutect2, varscan2
- DUSP22 | c.70G>T p.E24* | Nonsense Mutation (SNP) | VAF 46/343 reads (13%) | catalogued as COSV60524157, COSV60529701; called by muse, mutect2, varscan2
- EAPP | c.836A>G p.N279S | Missense Mutation (SNP) | VAF 92/260 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as rs149923274; called by muse, mutect2, varscan2
- ENOX2 | c.1066C>T p.R356W (on ENST00000338144 / NM_001382520.1; = p.R327W on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 109/341 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1169558988, COSV57656151; called by muse, mutect2, varscan2
- FASLG | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 126/362 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV60680677; called by muse, mutect2, varscan2
- FBN2 | c.3490C>T p.R1164C | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs886039059, COSV52534451; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FNDC1 | c.2411C>T p.T804M | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.649); catalogued as rs1262947803, COSV51938908; called by muse, mutect2, varscan2
- FRY | c.8680T>C p.S2894P | Missense Mutation (SNP) | VAF 72/208 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100969997; called by muse, mutect2, varscan2
- GABRA3 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 170/489 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1228855985, COSV64798895, COSV64800358; called by muse, mutect2, varscan2
- GDPD2 | c.1201C>T p.R401W | Missense Mutation (SNP) | VAF 80/257 reads (31%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.549); catalogued as rs755155591, COSV65533868; called by muse, mutect2, varscan2
- GIT1 | c.1715C>T p.P572L | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs763846891, COSV99838458; called by muse, mutect2, varscan2
- GJC1 | c.1018C>T p.R340W | Missense Mutation (SNP) | VAF 242/692 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs767836844, COSV57911189; called by muse, mutect2, varscan2
- GSR | c.1416A>C p.E472D | Missense Mutation (SNP) | VAF 208/597 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV55322325; called by muse, mutect2, varscan2
- HACE1 | c.1057A>G p.R353G | Missense Mutation (SNP) | VAF 146/525 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV53505740; called by muse, mutect2, varscan2
- HSPA6 | c.1623A>C p.K541N | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.156); catalogued as COSV59062123; called by muse, mutect2, varscan2
- HTR1D | c.800C>T p.S267L | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs376034704; called by muse, mutect2, varscan2
- ITIH2 | c.2707G>T p.D903Y | Missense Mutation (SNP) | VAF 66/225 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100623456; called by muse, mutect2, varscan2
- KCNA5 | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV52904329; called by muse, varscan2
- KCNA5 | c.496G>T p.D166Y | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781766067, COSV99363576, COSV99364248; called by muse, varscan2
- LCT | c.1240C>T p.R414C | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.586); catalogued as rs192524573, COSV51554892; called by muse, mutect2, varscan2
- LMBRD1 | c.1223G>A p.R408Q (on ENST00000649011; = p.R386Q on NM_018368.4) | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs772350306, COSV65296128; called by muse, mutect2, varscan2
- MAGEC1 | c.902C>A p.S301Y | Missense Mutation (SNP) | VAF 97/286 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.902); catalogued as COSV99596670; called by muse, varscan2
- MRO | c.429+1G>A p.X143_splice | Splice Site (SNP) | VAF 62/194 reads (32%) | catalogued as rs372190392, COSV99839601; called by muse, mutect2, varscan2
- MXRA5 | c.7289C>T p.T2430M | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.073); catalogued as rs376795964, COSV54235079; called by muse, varscan2
- MYOM2 | c.4385C>T p.A1462V | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.006); catalogued as rs778690685, COSV100038533; called by muse, mutect2, varscan2
- OR10A4 | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 111/746 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.086); catalogued as COSV101139612; called by muse, mutect2, varscan2
- OR10C1 | c.661C>T p.R221C (on ENST00000622521; = p.R219C on NM_013941.3) | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV65822599; called by muse, mutect2, varscan2
- OR10G9 | c.676C>T p.R226W | Missense Mutation (SNP) | VAF 210/584 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs770016884, COSV66686503; called by muse, mutect2, varscan2
- OR4K15 | c.706C>A p.L236I (on ENST00000305051; = p.L212I on NM_001005486.1) | Missense Mutation (SNP) | VAF 89/267 reads (33%) | SIFT tolerated (0.85); PolyPhen benign (0.034); catalogued as COSV100521184, COSV59300336; called by muse, mutect2, varscan2
- OTOF | c.3079G>A p.D1027N (on ENST00000272371 / NM_194248.3; = p.D280N on NM_004802.4) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as COSV55518942; called by muse, mutect2, varscan2
- PARP1 | c.2431G>A p.A811T | Missense Mutation (SNP) | VAF 57/166 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.244); catalogued as COSV64691643; called by muse, mutect2, varscan2
- PCARE | c.802C>A p.Q268K | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); catalogued as rs866543181, COSV100527923; called by muse, mutect2, varscan2
- PCCA | c.775C>G p.L259V | Missense Mutation (SNP) | VAF 37/459 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as rs373576351, CD991832; called by muse, mutect2
- PCDH11X | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.056); catalogued as COSV53438395; called by muse, mutect2, varscan2
- PCDHAC1 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1554204530, COSV53847946; called by muse, mutect2, varscan2
- PCDHGA3 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.086); catalogued as COSV99533838, COSV99548014; called by muse, mutect2, varscan2
- PCNT | c.1766G>A p.S589N | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100856089; called by muse, mutect2, varscan2
- PCNX1 | c.5675C>T p.A1892V | Missense Mutation (SNP) | VAF 125/393 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.982); catalogued as COSV99457449; called by muse, mutect2, varscan2
- PDE4A | c.1955C>T p.P652L (on ENST00000380702 / NM_001111307.2; = p.P413L on NM_006202.3) | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53360340; called by muse, mutect2, varscan2
- PGS1 | c.1093G>T p.D365Y | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53144140, COSV53147402; called by muse, mutect2, varscan2
- PHACTR3 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 52/142 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.085); catalogued as rs143288140, COSV63027760; called by muse, mutect2, varscan2
- PHKB | c.559T>G p.S187A | Missense Mutation (SNP) | VAF 62/611 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.062); catalogued as COSV54530165; called by muse, mutect2
- POLR1A | c.4432G>A p.A1478T | Missense Mutation (SNP) | VAF 186/576 reads (32%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs764220762, COSV99808530; called by muse, mutect2, varscan2
- PROSER2 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs775619900, COSV53205348; called by muse, mutect2, varscan2
- PTCHD1 | c.1028G>T p.G343V | Missense Mutation (SNP) | VAF 86/257 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV101038026; called by muse, mutect2, varscan2
- PTGER3 | c.323C>A p.P108Q | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100139746; called by muse, mutect2, varscan2
- RPTOR | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as rs1345238365, COSV60814753; called by muse, mutect2, varscan2
- RSPH10B2 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 83/270 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs767769813, COSV51870745; called by muse, mutect2, varscan2
- SHC4 | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV60109419; called by muse, mutect2, varscan2
- SLC28A3 | c.944T>A p.V315D | Missense Mutation (SNP) | VAF 70/186 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV66152584, COSV66154452; called by muse, mutect2, varscan2
- SLC4A9 | c.989C>A p.T330K (on ENST00000507527 / NM_001258428.2; = p.T306K on NM_031467.3) | Missense Mutation (SNP) | VAF 88/269 reads (33%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.967); catalogued as COSV50203720; called by muse, mutect2, varscan2
- SLC6A17 | c.1349C>T p.T450M | Missense Mutation (SNP) | VAF 53/137 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs201181747, COSV58995468; called by muse, mutect2, varscan2
- SLIT1 | c.2102C>A p.P701H | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99822637; called by muse, mutect2, varscan2
- SNX14 | c.932C>T p.P311L (on ENST00000314673 / NM_001350535.1; = p.P267L on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 73/184 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs764098295, COSV59010134; called by muse, mutect2, varscan2
- ST6GAL2 | c.1481G>A p.R494H | Missense Mutation (SNP) | VAF 34/90 reads (38%) | PolyPhen benign (0.362); catalogued as rs757962368, COSV62418156; called by muse, mutect2, varscan2
- TAAR2 | c.413C>T p.A138V (on ENST00000367931 / NM_001033080.1; = p.A93V on NM_014626.3) | Missense Mutation (SNP) | VAF 54/155 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754707698, COSV51579659; called by muse, mutect2, varscan2
- TAF1 | c.1212A>T p.K404N (on ENST00000373790 / NM_138923.4; = p.K425N on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 245/695 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99337177; called by muse, mutect2, varscan2
- TBC1D8 | c.3158C>T p.P1053L | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV51822689; called by muse, mutect2, varscan2
- TENM1 | c.479G>A p.G160D | Missense Mutation (SNP) | VAF 210/707 reads (30%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.27); catalogued as COSV100951115; called by muse, mutect2, varscan2
- TGFBR2 | c.968T>C p.L323P | Missense Mutation (SNP) | VAF 76/104 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55444207; called by muse, mutect2, varscan2
- TIAM2 | c.13G>A p.D5N | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); catalogued as rs551467133, COSV100020319; called by muse, mutect2, varscan2
- TMEM168 | c.116T>A p.L39* | Nonsense Mutation (SNP) | VAF 56/162 reads (35%) | catalogued as COSV57180477, COSV57181950; called by muse, mutect2, varscan2
- TOM1 | c.782G>A p.C261Y | Missense Mutation (SNP) | VAF 53/168 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65899082; called by muse, mutect2, varscan2
- TRIOBP | c.2108G>A p.R703Q | Missense Mutation (SNP) | VAF 20/498 reads (4%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.168); catalogued as rs779032542, COSV60375188; called by muse, mutect2
- UBQLN3 | c.1964C>T p.S655L | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs757646579, COSV61164391; called by muse, mutect2, varscan2
- UNC45B | c.2546G>T p.W849L | Missense Mutation (SNP) | VAF 109/325 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52097655, COSV52099089; called by muse, mutect2, varscan2
- WWC1 | c.2722C>T p.R908W | Missense Mutation (SNP) | VAF 71/197 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as rs549137219, COSV99516034; called by muse, mutect2, varscan2
- ZMYM6 | c.3685G>A p.D1229N | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs1207947073, COSV100593356; called by muse, mutect2, varscan2
- ZNF101 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58909752; called by muse, mutect2, varscan2
- ZNF175 | c.1792G>A p.G598S | Missense Mutation (SNP) | VAF 67/209 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.236); catalogued as rs1324690339, COSV51797466; called by muse, mutect2, varscan2
- ZNF318 | c.2651G>A p.R884H | Missense Mutation (SNP) | VAF 89/244 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753586964, COSV58936008; called by muse, mutect2, varscan2
- ZNF512B | c.914C>T p.P305L | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.019); catalogued as rs1414142381, COSV53875890; called by muse, mutect2, varscan2
- ZNF667 | c.43A>C p.T15P | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99411038; called by muse, mutect2
- ZNF99 | c.133A>T p.I45F | Missense Mutation (SNP) | VAF 71/220 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.327); catalogued as COSV68055974; called by muse, mutect2, varscan2
- INPP1 | c.152_153insTC p.L52Rfs*11 | Frame Shift Ins (INS) | VAF 71/242 reads (29%) | called by mutect2, varscan2
- RSPO3 | c.68A>C p.N23T | Missense Mutation (SNP) | VAF 24/273 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2
- SOX9 | c.1268del p.F423Sfs*47 | Frame Shift Del (DEL) | VAF 170/554 reads (31%) | called by mutect2, pindel, varscan2
- ADGRG4 | c.8247C>T p.T2749= | Silent (SNP) | VAF 212/624 reads (34%) | catalogued as rs917174614, COSV54963383; called by muse, mutect2
- CASP6 | c.99G>A p.P33= | Silent (SNP) | VAF 130/469 reads (28%) | catalogued as rs763084294, COSV54461589; called by muse, mutect2, varscan2
- CLCN5 | c.885C>A p.I295= | Silent (SNP) | VAF 250/731 reads (34%) | catalogued as COSV56585878; called by muse, mutect2, varscan2
- CLCN6 | c.2325C>T p.A775= | Silent (SNP) | VAF 52/164 reads (32%) | catalogued as rs762797912, COSV56741377; called by muse, mutect2, varscan2
- CXCL12 | c.222G>A p.P74= | Silent (SNP) | VAF 132/424 reads (31%) | catalogued as rs370748572; called by muse, mutect2, varscan2
- ELAPOR2 | c.984C>T p.D328= (on ENST00000450689 / NM_001142749.3; = p.D161= on NM_152748.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 77/266 reads (29%) | catalogued as rs774408868, COSV51890019, COSV51890104; called by muse, mutect2, varscan2
- ERLIN1 | c.741C>A p.I247= | Silent (SNP) | VAF 88/294 reads (30%) | catalogued as COSV64941142, COSV64941340; called by muse, mutect2, varscan2
- FAM110B | c.930C>T p.S310= | Silent (SNP) | VAF 49/147 reads (33%) | catalogued as rs775422320, COSV64067127; called by muse, mutect2, varscan2
- FLG | c.7596G>A p.S2532= | Silent (SNP) | VAF 98/233 reads (42%) | catalogued as rs142026832; called by muse, mutect2, varscan2
- FXYD6 | c.141C>T p.V47= | Silent (SNP) | VAF 66/257 reads (26%) | catalogued as COSV52804813; called by muse, mutect2, varscan2
- GRM5 | c.3363C>T p.I1121= (on ENST00000305447 / NM_001143831.2; = p.I1089= on NM_000842.4) | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs1194702399, COSV59613865, COSV59619900; called by muse, mutect2, varscan2
- HYOU1 | c.969C>T p.N323= | Silent (SNP) | VAF 31/99 reads (31%) | catalogued as rs376041557; called by muse, mutect2, varscan2
- LRRC4B | c.1695C>T p.L565= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV65350555; called by muse, mutect2, varscan2
- LYNX1 | c.304C>T p.L102= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV100235857; called by muse, mutect2, varscan2
- MANBA | c.2028C>G p.V676= (on ENST00000642252; = p.V630= on NM_005908.4) | Silent (SNP) | VAF 62/193 reads (32%) | catalogued as COSV56965360, COSV56968858; called by muse, mutect2, varscan2
- NOS1 | c.1713C>T p.A571= | Silent (SNP) | VAF 56/131 reads (43%) | catalogued as rs200268741, COSV57618323; called by muse, mutect2, varscan2
- NOXRED1 | c.354G>A p.E118= | Silent (SNP) | VAF 105/283 reads (37%) | catalogued as COSV53628792; called by muse, mutect2, varscan2
- OR10G8 | c.924T>G p.S308= | Silent (SNP) | VAF 49/152 reads (32%) | catalogued as COSV70909092; called by muse, mutect2, varscan2
- OR4E2 | c.549T>C p.L183= | Silent (SNP) | VAF 17/372 reads (5%) | catalogued as COSV100330168; called by muse, mutect2
- PCDH15 | c.1902T>A p.V634= | Silent (SNP) | VAF 132/360 reads (37%) | catalogued as COSV57365308; called by muse, varscan2
- PDE4DIP | c.5379C>T p.T1793= | Silent (SNP) | VAF 19/95 reads (20%) | catalogued as COSV57718461; called by muse, mutect2, varscan2
- PDHA2 | c.24C>T p.R8= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as rs745370766, COSV54778156; called by muse, mutect2, varscan2
- PGBD5 | c.90C>T p.P30= | Silent (SNP) | VAF 102/321 reads (32%) | catalogued as rs758104664, COSV58412980; called by muse, mutect2, varscan2
- RP1 | c.147C>T p.G49= | Silent (SNP) | VAF 48/136 reads (35%) | catalogued as rs571521776, COSV55111321; called by muse, varscan2
- SEMA6D | c.1383C>T p.N461= | Silent (SNP) | VAF 148/422 reads (35%) | catalogued as rs1347498228, COSV60381692; called by muse, mutect2, varscan2
- SLC24A1 | c.1272C>A p.P424= | Silent (SNP) | VAF 10/158 reads (6%) | catalogued as COSV99978622; called by muse, mutect2
- TSC1 | c.2055A>G p.S685= | Silent (SNP) | VAF 28/85 reads (33%) | catalogued as COSV53771166; called by muse, mutect2, varscan2
- UBA3 | c.1078A>C p.R360= | Silent (SNP) | VAF 157/383 reads (41%) | catalogued as COSV62741167; called by muse, mutect2, varscan2
- YTHDC1 | c.486T>G p.R162= | Silent (SNP) | VAF 34/88 reads (39%) | catalogued as COSV60011593; called by muse, mutect2, varscan2
- ZFHX4 | c.3657T>C p.C1219= | Silent (SNP) | VAF 110/376 reads (29%) | catalogued as COSV51483639; called by muse, varscan2
- DCHS2 | n.6450C>A | RNA (SNP) | VAF 56/176 reads (32%) | catalogued as COSV100602751; called by muse, mutect2, varscan2
- FBLN1 | c.1698-11275G>C | Intron (SNP) | VAF 12/32 reads (38%) | catalogued as COSV99411629; called by muse, mutect2, varscan2
- TFAP2A | chr6:10419451 C>T | 5'Flank (SNP) | VAF 69/174 reads (40%) | catalogued as COSV100117158; called by muse, mutect2, varscan2
